Somatic mutation profile of tumor specimen TCGA-22-5479-01A (aliquot TCGA-22-5479-01A-31D-1945-08) from TCGA case TCGA-22-5479, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.5 years (23,563 days).
Specimen TCGA-22-5479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f47c5374-d3a4-4a47-a136-962152720cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5479-11A (Solid Tissue Normal), aliquot TCGA-22-5479-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b5ec064-c245-47e0-8988-ead4a4355606

The open-access MAF lists 519 somatic variants for this specimen: 379 protein-altering or splice-affecting, 129 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 341, Silent 129, Nonsense Mutation 16, Splice Site 10, Frame Shift Del 6, RNA 5, Intron 5, Splice Region 4, 3'Flank 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP31 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 36/289 reads (12%) | catalogued as rs387907031, CM112971, COSV99956946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 22/64 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV100735747; called by muse, mutect2, varscan2
- ABCA13 | c.3323C>G p.S1108C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101330012; called by muse, mutect2, varscan2
- ABCA8 | c.1541T>C p.I514T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99285472; called by muse, mutect2, varscan2
- ABCC9 | c.3152T>A p.L1051H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99685384; called by muse, mutect2, varscan2
- ACSM4 | c.921C>T p.D307= | Splice Region (SNP) | VAF 33/180 reads (18%) | catalogued as rs747122297, COSV68069807; called by muse, mutect2, varscan2
- ACSM5 | c.824G>T p.W275L | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088751; called by muse, mutect2, varscan2
- ADAM28 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99738408; called by muse, mutect2, varscan2
- ADAMTS12 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100710689; called by muse, varscan2
- ADAMTS12 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100710690; called by muse, mutect2, varscan2
- ADAMTS12 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as COSV100710691, COSV61258767; called by muse, mutect2, varscan2
- ADCY4 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353136; called by muse, mutect2, varscan2
- ADGRL3 | c.1924G>A p.E642K (on ENST00000506720 / NM_001322402.2; = p.E574K on NM_015236.6) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100800343; called by muse, mutect2, varscan2
- ADPRHL1 | c.748A>C p.N250H | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100733408; called by muse, mutect2, varscan2
- ADRA2A | c.1320C>G p.I440M | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701599; called by muse, mutect2, varscan2
- AGGF1 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100461737; called by muse, mutect2, varscan2
- ALDH1L2 | c.2458T>C p.Y820H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV99310938; called by muse, mutect2, varscan2
- ALDH8A1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as COSV99664614; called by muse, mutect2, varscan2
- ALMS1 | c.4289C>G p.S1430* | Nonsense Mutation (SNP) | VAF 95/272 reads (35%) | catalogued as COSV100042059, COSV52521303; called by muse, mutect2, varscan2
- ALPK1 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as COSV99453748; called by muse, mutect2, varscan2
- AMDHD1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV57139331, COSV99900284; called by muse, mutect2, varscan2
- AMPD3 | c.939+1G>A p.X313_splice (on ENST00000396553 / NM_001025389.2; = p.X322_splice on NM_000480.3) | Splice Site (SNP) | VAF 50/124 reads (40%) | catalogued as COSV101158146; called by muse, mutect2, varscan2
- ANK2 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232729014, COSV52151937; called by muse, mutect2, varscan2
- ANKRD12 | c.304+1G>A p.X102_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100041098; called by muse, mutect2
- AP002512.3 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54405926, COSV99687874; called by muse, mutect2, varscan2
- APOOL | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920821; called by muse, varscan2
- ARHGAP21 | c.3111G>C p.E1037D | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100256056; called by muse, mutect2, varscan2
- ARHGAP31 | c.4151C>T p.S1384F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99956950; called by muse, mutect2, varscan2
- ARPC3 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99959509; called by muse, mutect2, varscan2
- ASTN2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.727); catalogued as rs554132287, COSV57804953; called by muse, mutect2, varscan2
- ASTN2 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV100526472, COSV57751743; called by muse, mutect2, varscan2
- ATG9B | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV99871496; called by muse, mutect2, varscan2
- ATP10A | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as rs17854738, COSV100791103, COSV63515206; called by muse, mutect2, varscan2
- ATP4A | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV99382432, COSV99382914; called by muse, mutect2, varscan2
- B3GALT1 | c.542T>C p.F181S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100002636; called by muse, mutect2, varscan2
- B3GNT3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs1273897138, COSV100592707; called by muse, mutect2, varscan2
- BCAR1 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV99366468; called by muse, mutect2
- BMP3 | c.1000A>T p.N334Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99261549; called by muse, mutect2, varscan2
- BTBD17 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100945295; called by muse, mutect2, varscan2
- BTBD7 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV100108002; called by muse, mutect2, varscan2
- C16orf71 | c.1461C>A p.S487R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs752865697, COSV99556254; called by muse, mutect2, varscan2
- CA13 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs771065915, COSV100410027; called by muse, mutect2, varscan2
- CACNA1C | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 57/902 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100217778; called by muse, mutect2
- CAMKV | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV99615378; called by muse, varscan2
- CAPN5 | c.1829G>A p.R610H (on ENST00000456580; = p.R570H on NM_004055.5) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141138795, COSV53691337; called by muse, mutect2, varscan2
- CCDC7 | c.2812T>A p.S938T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV100178068; called by muse, mutect2, varscan2
- CCDC90B | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV52624915; called by muse, mutect2, varscan2
- CDC20B | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99696771; called by muse, mutect2, varscan2
- CDCA2 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs747766762, COSV100398828; called by muse, mutect2, varscan2
- CDK6 | c.234-2A>T p.X78_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as rs1198162086, COSV99721067; called by muse, mutect2, varscan2
- CEBPD | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99854781; called by mutect2, varscan2
- CEP112 | c.97C>G p.H33D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV67144421; called by muse, mutect2
- CEP120 | c.1166A>T p.H389L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100071000; called by muse, varscan2
- CEP164 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); catalogued as COSV99633075; called by muse, mutect2, varscan2
- CEP97 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs140096758, COSV100511657; called by muse, varscan2
- CEP97 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.134); catalogued as COSV100511659; called by muse, varscan2
- CLCN6 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56740614; called by muse, mutect2, varscan2
- CLCN6 | c.2492G>A p.G831D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100411825; called by muse, mutect2, varscan2
- CMYA5 | c.11785A>T p.T3929S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as rs1482320394, COSV101405655; called by muse, mutect2, varscan2
- CNOT2 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | catalogued as COSV99972547; called by muse, mutect2
- CNOT3 | c.2151C>G p.D717E | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV99651698; called by muse, mutect2
- CNTNAP2 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV100665182, COSV62208741; called by muse, mutect2, varscan2
- COL11A2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.933); catalogued as rs751864384, COSV100553777; called by muse, mutect2, varscan2
- COL19A1 | c.1278+2T>C p.X426_splice | Splice Site (SNP) | VAF 19/106 reads (18%) | catalogued as COSV100506043; called by muse, mutect2, varscan2
- COL19A1 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773422506, COSV100506045; called by muse, mutect2, varscan2
- COL1A2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51954105; called by muse, mutect2, varscan2
- COL24A1 | c.3035C>G p.P1012R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100993160, COSV100993795; called by muse, mutect2, varscan2
- COL4A4 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV100306621; called by muse, mutect2, varscan2
- COL4A6 | c.2689G>T p.G897* | Nonsense Mutation (SNP) | VAF 79/140 reads (56%) | catalogued as COSV100563911; called by muse, mutect2, varscan2
- CSMD1 | c.3825A>T p.I1275= (on ENST00000520002; = p.I1274= on NM_033225.6) | Splice Region (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100146678; called by muse, mutect2, varscan2
- CSMD1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101219321; called by muse, mutect2, varscan2
- CSMD1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101219322, COSV101221712; called by muse, mutect2, varscan2
- CSMD3 | c.4113C>G p.H1371Q (on ENST00000297405 / NM_001363185.1; = p.H1267Q on NM_052900.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99831367; called by muse, mutect2, varscan2
- CUX2 | c.3082T>G p.Y1028D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99919361; called by muse, mutect2, varscan2
- CYFIP2 | c.2800G>C p.G934R (on ENST00000616178 / NM_001291722.2; = p.G909R on NM_014376.4) | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100556419; called by muse, mutect2, varscan2
- CYP3A43 | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs377124793; called by muse, mutect2, varscan2
- DACH1 | c.1868C>T p.T623I (on ENST00000619232 / NM_001366712.1; = p.T369I on NM_004392.6) | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV100498092, COSV57499424, COSV57513214; called by muse, mutect2, varscan2
- DAGLB | c.1379A>T p.Y460F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV99765788; called by muse, mutect2, varscan2
- DEFB131A | c.11T>C p.L4S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as COSV100607841; called by muse, mutect2, varscan2
- DGKI | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.157); catalogued as COSV99933634; called by muse, mutect2, varscan2
- DNAAF4 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV100336511; called by muse, mutect2, varscan2
- DNAH11 | c.5263G>A p.G1755R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100178665; called by muse, mutect2, varscan2
- DNAH5 | c.8625G>C p.L2875F | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99448332; called by muse, mutect2
- DNAH5 | c.2137C>G p.Q713E | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99448337; called by muse, mutect2
- DNAH6 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | catalogued as COSV52886158; called by muse, mutect2, varscan2
- DOC2A | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs1339517579, COSV100451240; called by muse, mutect2, varscan2
- DOCK2 | c.1056-2A>C p.X352_splice | Splice Site (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99911577; called by muse, mutect2, varscan2
- DOP1B | c.5848G>A p.A1950T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101215252; called by muse, mutect2, varscan2
- DPPA2 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1452775948, COSV101524752; called by muse, mutect2, varscan2
- DPY19L2 | c.1344A>T p.L448F | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.168); catalogued as COSV100116672; called by muse, mutect2, varscan2
- DSG4 | c.1908G>A p.M636I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100355719; called by muse, mutect2, varscan2
- EDIL3 | c.1095T>A p.N365K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675858; called by muse, mutect2, varscan2
- EGF | c.2522G>T p.S841I | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV54484681, COSV99490761; called by muse, mutect2, varscan2
- ENC1 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs368405991; called by muse, varscan2
- EPB41L3 | c.1721G>A p.S574N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59454499; called by muse, mutect2, varscan2
- EPB41L4B | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV101000893; called by muse, mutect2
- EPDR1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554341; called by muse, mutect2
- EPO | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV53161447, COSV99402559; called by muse, mutect2, varscan2
- EXD1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100153580, COSV59252513; called by muse, mutect2, varscan2
- FAHD2A | c.795G>A p.Q265= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99271967; called by muse, mutect2, varscan2
- FAM135B | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99356809; called by muse, mutect2, varscan2
- FAM53C | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs539762304, COSV99524328; called by muse, mutect2, varscan2
- FAM83H | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1554621659, COSV100567812; called by muse, mutect2, varscan2
- FAT3 | c.4195G>T p.G1399W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961552; called by muse, mutect2, varscan2
- FAT4 | c.4525C>G p.R1509G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV101272246, COSV67880799; called by muse, mutect2, varscan2
- FCGRT | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99675265; called by muse, mutect2
- FMN2 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.378); catalogued as COSV60419258, COSV60445924; called by muse, mutect2, varscan2
- FOXS1 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99639534, COSV99639661; called by muse, mutect2, varscan2
- FSCB | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs1484795529, COSV61218957; called by muse, mutect2, varscan2
- FSTL4 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99532212; called by muse, mutect2, varscan2
- FZD2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100190355; called by muse, mutect2
- GABRR3 | c.845T>A p.V282E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101512278; called by muse, mutect2, varscan2
- GANAB | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100647770, COSV100647967, COSV60462224; called by muse, mutect2, varscan2
- GIPR | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV99624582; called by muse, mutect2, varscan2
- GLB1L3 | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV101345130; called by muse, varscan2
- GOLGB1 | c.8204C>G p.S2735C | Missense Mutation (SNP) | VAF 19/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61468691; called by muse, mutect2
- GOLGB1 | c.4583C>G p.S1528C | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.965); catalogued as COSV100510668; called by muse, mutect2
- GOT1L1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100294438; called by muse, mutect2, varscan2
- GPATCH3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.026); catalogued as COSV100658758; called by muse, mutect2
- GPR119 | c.1000G>C p.D334H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99358603; called by muse, mutect2, varscan2
- GPR12 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.792); catalogued as COSV101197967; called by muse, mutect2, varscan2
- GPR63 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100013272; called by muse, mutect2, varscan2
- GPX6 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV100724810; called by muse, mutect2, varscan2
- GSC | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99450172; called by muse, mutect2, varscan2
- GZMA | c.470A>G p.H157R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV57057061; called by muse, mutect2, varscan2
- HBE1 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99496142; called by muse, mutect2, varscan2
- HDAC3 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99781304; called by muse, mutect2, varscan2
- HDAC4 | c.3145G>T p.E1049* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100613204, COSV61859604; called by mutect2, varscan2
- HDAC7 | c.1874C>G p.T625S (on ENST00000427332; = p.T664S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99315941; called by muse, mutect2
- HDC | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99983948; called by muse, mutect2, varscan2
- HEATR5A | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV101119873; called by muse, mutect2, varscan2
- HEPHL1 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV59889485, COSV59897318; called by muse, mutect2, varscan2
- HERC1 | c.7511G>C p.R2504T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV101496505; called by muse, mutect2
- HHIPL2 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs774697746, COSV58564862, COSV58565498; called by muse, mutect2, varscan2
- HMG20A | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.717); catalogued as COSV100287725; called by muse, varscan2
- HMGN1 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV55743128, COSV99903261; called by muse, mutect2, varscan2
- HSPA8 | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.033); catalogued as COSV99914337; called by muse, mutect2, varscan2
- HYOU1 | c.2756A>C p.K919T | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV101345576; called by muse, mutect2
- IFIH1 | c.2146G>T p.E716* | Nonsense Mutation (SNP) | VAF 21/213 reads (10%) | catalogued as COSV99718582; called by muse, mutect2
- IFNA7 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV53332497, COSV99497445; called by muse, mutect2, varscan2
- IGHV4-59 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs782717265; called by muse, mutect2, varscan2
- ILDR2 | c.1166C>G p.S389* | Nonsense Mutation (SNP) | VAF 46/386 reads (12%) | catalogued as COSV99613628; called by muse, mutect2, varscan2
- IMPDH2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100455003, COSV100455110; called by muse, mutect2, varscan2
- ITIH2 | c.2293T>A p.Y765N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.532); catalogued as COSV100623256; called by muse, mutect2, varscan2
- JAG2 | c.1905G>C p.E635D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1232372334, COSV100078167; called by muse, mutect2
- JAG2 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV100078120, COSV59307543; called by muse, mutect2, varscan2
- KALRN | c.8775G>T p.R2925S (on ENST00000360013 / NM_001024660.4; = p.R1228S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.319); catalogued as COSV99361731; called by muse, mutect2, varscan2
- KCNIP3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99733955; called by muse, mutect2, varscan2
- KCNJ2 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99696321; called by muse, mutect2, varscan2
- KCNJ3 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV54535382, COSV99715582; called by muse, mutect2, varscan2
- KCNK17 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64686070; called by muse, mutect2, varscan2
- KCNK6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371310407; called by muse, mutect2, varscan2
- KDM1A | c.2230A>G p.K744E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); catalogued as COSV100173788; called by muse, mutect2, varscan2
- KIAA0586 | c.809T>A p.V270D (on ENST00000619416 / NM_001244190.2; = p.V285D on NM_014749.5) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV99707931; called by muse, mutect2, varscan2
- KIAA1958 | c.2013G>C p.Q671H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100515995; called by muse, mutect2, varscan2
- KIAA2026 | c.2707A>T p.I903L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV101198962; called by muse, mutect2, varscan2
- KIR3DL3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1213548019; called by muse, mutect2, varscan2
- KLHL36 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99256719; called by muse, mutect2, varscan2
- KLK8 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.025); catalogued as COSV99143945; called by muse, mutect2, varscan2
- KMT2C | c.6658C>T p.Q2220* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV51352652; called by muse, mutect2, varscan2
- KMT2D | c.10554G>T p.Q3518H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99980130; called by muse, varscan2
- KRT16 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs150387381, COSV100052910; called by muse, mutect2, varscan2
- KRT38 | c.175T>A p.S59T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99878163; called by muse, mutect2, varscan2
- LAMA1 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055942; called by muse, mutect2, varscan2
- LCMT2 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59790960, COSV99980028; called by muse, mutect2, varscan2
- LRP2 | c.3767G>T p.C1256F | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55574260; called by muse, mutect2
- LRRC74A | c.1283T>C p.V428A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV99372394; called by muse, mutect2
- LYST | c.6338C>T p.S2113L | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); catalogued as COSV101089049; called by muse, mutect2
- MAGEB6 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as COSV100983717; called by muse, mutect2, varscan2
- MAGEE2 | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100973047; called by muse, mutect2, varscan2
- MED23 | c.2559G>T p.M853I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.644); catalogued as COSV100644904; called by muse, mutect2, varscan2
- MEIS3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs534956649, COSV58985382; called by muse, mutect2, varscan2
- MFSD1 | c.1176-2A>G p.X392_splice | Splice Site (SNP) | VAF 105/418 reads (25%) | catalogued as COSV99963748; called by muse, mutect2, varscan2
- MICALL1 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1006475452, COSV53240783; called by muse, mutect2, varscan2
- MLN | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV99803101; called by muse, mutect2, varscan2
- MNDA | c.1105C>A p.L369I | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100933301; called by muse, mutect2, varscan2
- MROH2B | c.3394G>A p.D1132N | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.797); catalogued as COSV101270629; called by muse, mutect2
- MUC17 | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as COSV100072729; called by muse, mutect2, varscan2
- MUC17 | c.6901A>G p.T2301A | Missense Mutation (SNP) | VAF 88/422 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as rs745802262, COSV100072730; called by muse, mutect2, varscan2
- MYL1 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV100498685; called by muse, mutect2, varscan2
- MYO10 | c.5425G>C p.E1809Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57029371; called by muse, mutect2
- NAA15 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV56723376; called by muse, mutect2, varscan2
- NBEAL1 | c.5818G>C p.E1940Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101355453, COSV101355502; called by muse, mutect2, varscan2
- NCAPD2 | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV100217060; called by muse, mutect2
- NCSTN | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.165); catalogued as COSV99667036; called by muse, mutect2
- NETO1 | c.528G>T p.M176I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV100198515; called by muse, mutect2, varscan2
- NEUROG2 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.052); catalogued as COSV100511803, COSV57637849; called by muse, mutect2
- NFIB | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66620559; called by muse, mutect2, varscan2
- NLRP5 | c.1479del p.F494Sfs*35 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as COSV101173593; called by mutect2, varscan2
- NPAS3 | c.188G>A p.R63H (on ENST00000356141 / NM_001164749.2; = p.R33H on NM_022123.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416144955, COSV58092903, COSV58104079; called by muse, mutect2, varscan2
- NR2C1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV100280407; called by muse, mutect2, varscan2
- NR4A3 | c.1352G>T p.W451L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58246059; called by muse, mutect2, varscan2
- NRG2 | c.956A>T p.K319M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99180051; called by muse, mutect2, varscan2
- NRK | c.4350G>C p.K1450N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54599764, COSV99687401; called by muse, mutect2, varscan2
- NSD1 | c.7162C>T p.P2388S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV100728809; called by muse, mutect2, varscan2
- NUP54 | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99345236; called by muse, mutect2, varscan2
- NXPH2 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99740435; called by muse, mutect2, varscan2
- OBI1 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs781417275, COSV99932417; called by muse, varscan2
- OGDH | c.2881A>T p.K961* | Nonsense Mutation (SNP) | VAF 38/157 reads (24%) | catalogued as COSV99758651; called by muse, mutect2, varscan2
- OLFM3 | c.605G>C p.R202T (on ENST00000338858 / NM_001288821.1; = p.R182T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV100129232; called by muse, mutect2, varscan2
- OPTN | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99537413; called by muse, mutect2, varscan2
- OR10K2 | c.762T>G p.C254W | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149463; called by muse, mutect2, varscan2
- OR14A16 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100713753; called by muse, mutect2, varscan2
- OR1A1 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100410745; called by muse, mutect2, varscan2
- OR2B11 | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV59509742, COSV59511326; called by muse, mutect2, varscan2
- OR2L8 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100594131; called by muse, mutect2
- OR2T10 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100393641, COSV57896246; called by muse, mutect2, varscan2
- OR2T11 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763763659, COSV100424771; called by muse, varscan2
- OR4K13 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1001180230, COSV100237707; called by muse, mutect2, varscan2
- OR51I2 | c.938G>C p.*313Sext*? | Nonstop Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100413375; called by muse, mutect2, varscan2
- OR5J2 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100398979; called by muse, mutect2, varscan2
- OR5L2 | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV65723301, COSV65724665; called by muse, mutect2, varscan2
- OR6B1 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.903); catalogued as COSV101281645; called by muse, mutect2, varscan2
- OR9G1 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380355; called by muse, mutect2
- PCDH11X | c.1876C>G p.R626G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV100010956; called by muse, mutect2, varscan2
- PCDH9 | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119767; called by mutect2, varscan2
- PCDHB3 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as rs143918470, COSV99164891; called by muse, mutect2, varscan2
- PCDHB7 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV99176815; called by muse, mutect2, varscan2
- PCDHGA1 | c.1445A>G p.N482S | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); catalogued as COSV100965979; called by muse, mutect2, varscan2
- PCDHGA7 | c.2284G>C p.D762H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV53969575, COSV99535766; called by muse, mutect2, varscan2
- PDE3A | c.2837T>C p.I946T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100762042; called by muse, mutect2, varscan2
- PDE3A | c.3347T>C p.I1116T | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62970444; called by muse, mutect2, varscan2
- PHKA2 | c.2396A>G p.H799R | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101176953; called by muse, mutect2, varscan2
- PIK3R1 | c.1885A>G p.S629G (on ENST00000521381 / NM_181523.3; = p.S359G on NM_181504.4) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV99142490; called by muse, mutect2, varscan2
- PIK3R2 | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.154); catalogued as COSV99717336; called by muse, mutect2, varscan2
- PJA1 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV100824701, COSV64053838; called by mutect2, varscan2
- PJVK | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1559368467, COSV100359532; called by muse, mutect2, varscan2
- PKN3 | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99403507; called by muse, mutect2, varscan2
- PLOD1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs748111731, COSV99538132; called by muse, mutect2, varscan2
- PLXND1 | c.4394A>T p.E1465V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV100139529; called by muse, mutect2, varscan2
- PMAIP1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV99504841; called by muse, mutect2, varscan2
- PML | c.1866G>T p.Q622H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV99166902, COSV99167634; called by muse, mutect2, varscan2
- POT1 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1021547035, COSV100714046; called by muse, varscan2
- PPFIA2 | c.1450T>A p.L484I | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100332797; called by muse, mutect2, varscan2
- PPP1R9A | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs761125411, COSV99195285; called by muse, mutect2, varscan2
- PPP1R9A | c.2669C>A p.S890Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV99195288; called by muse, mutect2, varscan2
- PPP3CA | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV100547524, COSV59931746; called by muse, mutect2, varscan2
- PRDM15 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs777471493, COSV99519901; called by muse, mutect2, varscan2
- PRSS16 | c.670-1G>A p.X224_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100041670; called by muse, mutect2, varscan2
- PTOV1 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99681670; called by muse, mutect2, varscan2
- PTPN4 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55302721, COSV99749982; called by muse, mutect2, varscan2
- PTPRC | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100722478; called by muse, mutect2, varscan2
- PXDNL | c.3486G>C p.L1162F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100683071; called by muse, mutect2, varscan2
- RAB27A | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs151048993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAG1 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.013); catalogued as COSV100200834; called by muse, mutect2, varscan2
- RASA3 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.542); catalogued as COSV100480343; called by muse, varscan2
- RBM19 | c.2349G>T p.K783N | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV55699979, COSV99925894; called by mutect2, varscan2
- REG3G | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV55452543, COSV99709375; called by muse, mutect2, varscan2
- RELN | c.7175G>C p.C2392S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as COSV100633326; called by muse, mutect2, varscan2
- RELN | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633327; called by muse, mutect2, varscan2
- RIMS1 | c.2899T>A p.S967T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99325854; called by muse, mutect2, varscan2
- RIOK1 | c.1222C>G p.Q408E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99344696; called by muse, varscan2
- RNF38 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99424956; called by muse, mutect2, varscan2
- RNF38 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424959; called by muse, mutect2, varscan2
- RPE65 | c.1206G>T p.W402C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV52018398, COSV99253790; called by muse, mutect2, varscan2
- RPL10L | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100022497; called by muse, mutect2, varscan2
- RPRD2 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.832); catalogued as rs1553876932, COSV100954710; called by muse, mutect2, varscan2
- RSF1 | c.3088A>G p.I1030V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100407088; called by muse, mutect2, varscan2
- RTN1 | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99955311; called by muse, mutect2, varscan2
- RXFP1 | c.1987T>C p.S663P | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100313689; called by muse, mutect2
- RYR2 | c.10618G>A p.D3540N | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as COSV63665120; called by muse, mutect2, varscan2
- RYR3 | c.3650G>C p.G1217A | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212513; called by muse, mutect2
- SACS | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.09); catalogued as COSV101207383; called by muse, mutect2, varscan2
- SERPINB4 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302198919, COSV100345618; called by muse, mutect2, varscan2
- SETDB2 | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99320674; called by muse, mutect2, varscan2
- SGCE | c.1135C>T p.R379W (on ENST00000647096; = p.R343W on NM_003919.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757796461, COSV99722438; called by muse, mutect2, varscan2
- SGO2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV63414606; called by muse, mutect2, varscan2
- SH2D5 | c.862G>A p.E288K (on ENST00000444387 / NM_001103161.2; = p.E204K on NM_001103160.2) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs764616867, COSV66706535; called by muse, mutect2, varscan2
- SH3GL2 | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV101014224; called by muse, mutect2, varscan2
- SIGLEC14 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99707405; called by muse, mutect2, varscan2
- SIPA1L2 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs986466911, COSV53390697, COSV99477919; called by muse, mutect2
- SLC10A2 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV99079269, COSV99807860; called by muse, mutect2
- SLC12A1 | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373506202, COSV101118545; called by muse, mutect2, varscan2
- SLC12A1 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556137575, COSV101118547; called by muse, mutect2, varscan2
- SLC13A1 | c.1350G>A p.E450= | Splice Region (SNP) | VAF 16/131 reads (12%) | catalogued as rs1343011382, COSV99520740; called by muse, mutect2, varscan2
- SLC15A1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268100392, COSV100919458; called by muse, mutect2, varscan2
- SLC22A10 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as rs748176638, COSV100235686; called by muse, mutect2, varscan2
- SLC35A5 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99656753; called by muse, mutect2, varscan2
- SLC5A4 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV99831849; called by muse, mutect2, varscan2
- SLC5A7 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99886552, COSV99887127; called by muse, mutect2, varscan2
- SLC6A11 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99594372; called by muse, mutect2, varscan2
- SLC8A1 | c.1525A>T p.I509L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs577937330, COSV100245569; called by muse, mutect2, varscan2
- SLC8A3 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100776088, COSV100776089; called by muse, mutect2
- SLCO1B1 | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99918303; called by muse, mutect2, varscan2
- SLCO2A1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV100188875; called by muse, mutect2, varscan2
- SLITRK6 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV101233211; called by muse, mutect2, varscan2
- SOGA1 | c.1220A>T p.K407M | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1399270699, COSV99413477; called by muse, mutect2, varscan2
- SORCS1 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV53910230, COSV99545308; called by muse, mutect2, varscan2
- SPATA31A3 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as rs376712024; called by muse, mutect2, varscan2
- SPHKAP | c.3647G>A p.S1216N | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60885895; called by muse, mutect2, varscan2
- SS18L1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.184); catalogued as COSV100064787; called by muse, varscan2
- ST18 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99389182; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.732-2A>T p.X244_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as rs1430636570, COSV100082642, COSV100085460; called by muse, mutect2
- STAB2 | c.2183G>T p.C728F | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101185870; called by muse, mutect2, varscan2
- STEAP4 | c.1352A>T p.Q451L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100112519; called by muse, mutect2, varscan2
- STK32C | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100062255; called by muse, mutect2
- STRA8 | c.734T>C p.I245T (on ENST00000275764; = p.I223T on NM_182489.2) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99312378; called by muse, mutect2, varscan2
- STYXL2 | c.1883A>T p.E628V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99609011; called by muse, mutect2, varscan2
- SUSD4 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.712); catalogued as COSV100663679; called by muse, mutect2, varscan2
- TAS2R1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.269); catalogued as COSV101225745; called by muse, mutect2, varscan2
- TBC1D14 | c.1821C>G p.F607L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV101298875; called by muse, mutect2, varscan2
- TBX3 | c.794A>G p.Y265C (on ENST00000257566 / NM_016569.4; = p.Y245C on NM_005996.4) | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99983682; called by muse, mutect2, varscan2
- TBX5 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100091029; called by muse, mutect2, varscan2
- TBX5 | c.657C>A p.N219K | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100091032; called by muse, mutect2, varscan2
- TESK2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.534); catalogued as COSV100517254, COSV59149476, COSV59156710; called by muse, mutect2, varscan2
- TFAP2D | c.28C>A p.H10N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV50412186, COSV99145857; called by muse, mutect2, varscan2
- THBS2 | c.2737C>T p.R913W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142602633, COSV100827818; called by muse, mutect2, varscan2
- THSD7A | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV101439741; called by muse, mutect2
- THSD7A | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV101448644, COSV70264999; called by muse, mutect2, varscan2
- TMPRSS11E | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100542309; called by muse, mutect2, varscan2
- TMTC4 | c.1979A>T p.N660I (on ENST00000376234 / NM_001350577.2; = p.N679I on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV60892541; called by muse, mutect2, varscan2
- TNC | c.2702G>T p.R901L | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as COSV100405534; called by muse, varscan2
- TNFRSF8 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821350; called by muse, mutect2
- TNPO2 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100790327; called by muse, mutect2, varscan2
- TOE1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100517252; called by muse, mutect2, varscan2
- TONSL | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV101340208; called by muse, mutect2
- TP53 | c.455_456insT p.P153Afs*28 | Frame Shift Ins (INS) | VAF 29/89 reads (33%) | catalogued as COSV53468298, COSV99394349; called by mutect2, pindel, varscan2
- TPM3 | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99666280; called by muse, mutect2
- TPTE2 | c.367G>T p.V123F (on ENST00000400230 / NM_199254.2; = p.V86F on NM_130785.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99690121; called by muse, varscan2
- TRIM58 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100825029; called by muse, mutect2, varscan2
- TRIOBP | c.3836C>G p.P1279R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV100730797; called by muse, mutect2, varscan2
- TRMT12 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758133432, COSV100149152; called by mutect2, varscan2
- TTBK2 | c.1898A>G p.Y633C | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99141327; called by muse, mutect2, varscan2
- TTN | c.99430G>A p.E33144K (on ENST00000591111; = p.E25720K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | PolyPhen benign (0.121); catalogued as COSV100605643; called by muse, mutect2, varscan2
- TTN | c.78398C>A p.T26133N (on ENST00000591111; = p.T18709N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | PolyPhen benign (0); catalogued as COSV100605650; called by muse, varscan2
- UBOX5 | c.1170G>C p.L390F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.417); catalogued as COSV99417706; called by muse, mutect2
- UGT2B11 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1041996132, COSV101485239, COSV101485246; called by muse, mutect2
- UNC13B | c.2438T>G p.M813R | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV101036548; called by muse, mutect2, varscan2
- UNG | c.284G>C p.G95A (on ENST00000242576 / NM_080911.3; = p.G86A on NM_003362.4) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV99655291; called by muse, mutect2, varscan2
- UPP2 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV99134831; called by muse, mutect2, varscan2
- USF3 | c.5584C>T p.H1862Y | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100325079; called by muse, mutect2
- USP45 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.389); catalogued as COSV100328126; called by muse, mutect2
- UTP6 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99911892; called by muse, mutect2, varscan2
- VCAM1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV54120784, COSV99658434; called by muse, mutect2, varscan2
- VCPIP1 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60047413, COSV60050141; called by muse, mutect2, varscan2
- VPS13A | c.9023G>A p.R3008K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100652523; called by muse, mutect2, varscan2
- VPS13D | c.6908G>C p.R2303T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99166137; called by muse, mutect2, varscan2
- VPS13D | c.12989C>T p.T4330M | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs34128167; called by muse, mutect2, varscan2
- VSTM1 | c.610G>C p.V204L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV100618756; called by muse, mutect2, varscan2
- VWA3B | c.654C>G p.S218R | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV101346003; called by muse, mutect2, varscan2
- WDFY3 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 20/158 reads (13%) | catalogued as COSV55704884, COSV99883587; called by muse, mutect2, varscan2
- WDR25 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58939072; called by muse, mutect2, varscan2
- WDR59 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100049166; called by muse, mutect2, varscan2
- XIRP2 | c.9696G>T p.R3232S (on ENST00000628543; = p.R3407S on NM_152381.6) | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs541668021, COSV54687444; called by muse, mutect2, varscan2
- XRCC5 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101079460; called by muse, mutect2, varscan2
- ZAN | c.7321G>A p.E2441K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV100769574; called by muse, mutect2, varscan2
- ZFHX4 | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV99261311; called by muse, mutect2, varscan2
- ZFHX4 | c.10217G>C p.R3406T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99261316; called by muse, mutect2
- ZIC1 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV99291784; called by muse, mutect2, varscan2
- ZNF202 | c.1280G>T p.C427F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278933, COSV100278993; called by muse, mutect2
- ZNF208 | c.1979C>A p.A660D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV101236974, COSV101236985; called by muse, varscan2
- ZNF257 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs757091730, COSV101448171, COSV71310220; called by muse, mutect2, varscan2
- ZNF287 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV101209365; called by muse, mutect2, varscan2
- ZNF345 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763960472, COSV100080234; called by muse, mutect2, varscan2
- ZNF367 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs925466166, COSV100930852; called by muse, mutect2, varscan2
- ZNF394 | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100460123; called by muse, mutect2, varscan2
- ZNF398 | c.848C>G p.S283C (on ENST00000475153 / NM_170686.3; = p.S112C on NM_020781.4) | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100246879; called by muse, mutect2, varscan2
- ZNF431 | c.1619A>G p.Y540C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs368492406; called by muse, mutect2, varscan2
- ZNF512B | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.904); catalogued as rs746049582, COSV99411840; called by muse, mutect2, varscan2
- ZNF518B | c.3130C>G p.L1044V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.289); catalogued as COSV100456660; called by muse, mutect2
- ZNF560 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV56871765; called by muse, mutect2, varscan2
- ZNF639 | c.367C>G p.Q123E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100418410; called by muse, mutect2
- ZNF827 | c.241T>G p.L81V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV101061272; called by muse, mutect2, varscan2
- ZNF98 | c.1679A>G p.K560R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100757405; called by muse, mutect2, varscan2
- ZNF98 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs577683093, COSV63333951, COSV63335177; called by muse, mutect2, varscan2
- CCDC54 | c.690del p.S231Afs*21 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, varscan2
- COL26A1 | c.974del p.P325Qfs*24 (on ENST00000313669 / NM_001278563.3; = p.P323Qfs*24 on NM_133457.4) | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- DIS3L | c.857del p.N286Tfs*9 (on ENST00000319212 / NM_001143688.3; = p.N203Tfs*9 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- FAR2 | c.366-3_366-2del p.X122_splice | Splice Site (DEL) | VAF 26/200 reads (13%) | called by mutect2, pindel, varscan2
- GTF2E1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- IGHG4 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV2-26 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRSN2 | c.352del p.A118Qfs*21 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, varscan2
- SRP72 | c.946_957+6del p.X316_splice | Splice Site (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- SRSF7 | c.399_418del p.S134Kfs*30 | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | called by mutect2, pindel, varscan2
- TRAV24 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TRBV19 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- AC011462.1 | c.1065C>T p.N355= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99524534; called by muse, mutect2
- ACTN3 | c.2253C>T p.T751= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs775628112, COSV100074226; called by muse, mutect2, varscan2
- AMY1C | c.975C>G p.A325= | Silent (SNP) | VAF 97/919 reads (11%) | catalogued as rs752563555, COSV100915200, COSV100915207; called by muse, mutect2, varscan2
- AMY2B | c.963G>T p.G321= | Silent (SNP) | VAF 60/349 reads (17%) | catalogued as COSV100796269; called by muse, mutect2, varscan2
- ANKRD12 | c.3861G>A p.R1287= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100041100; called by muse, mutect2, varscan2
- ANKS1A | c.3150C>T p.I1050= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs765149162, COSV100832276; called by muse, mutect2, varscan2
- AOC1 | c.1182C>T p.T394= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1334547709, COSV100710726; called by muse, mutect2, varscan2
- ARHGAP30 | c.159C>A p.I53= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100920203; called by muse, mutect2
- ATP8A1 | c.1107C>G p.T369= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100045749; called by muse, mutect2, varscan2
- ATR | c.7497C>T p.F2499= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100638045, COSV100638284; called by muse, mutect2
- AVIL | c.1785G>T p.L595= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV57681551; called by muse, mutect2, varscan2
- BAHCC1 | c.7752C>T p.D2584= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs782010573, COSV100311479; called by muse, mutect2, varscan2
- BRINP1 | c.1408C>A p.R470= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99775127; called by muse, mutect2, varscan2
- C20orf96 | c.315C>T p.L105= (on ENST00000360321 / NM_153269.3; = p.L104= on NM_080571.1) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100826703; called by muse, varscan2
- C5orf38 | c.315G>T p.P105= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV100121562; called by muse, mutect2
- C7orf31 | c.990G>A p.P330= | Silent (SNP) | VAF 17/219 reads (8%) | catalogued as rs142070400, COSV52218807, COSV99383886; called by muse, mutect2
- C9orf131 | c.3084C>A p.I1028= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV100398028; called by muse, mutect2, varscan2
- CACNA1C | c.2850G>A p.L950= | Silent (SNP) | VAF 38/540 reads (7%) | catalogued as COSV100217779; called by muse, mutect2
- CCDC184 | c.294C>A p.R98= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100343931; called by muse, mutect2, varscan2
- CD63 | c.189C>T p.F63= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV57676451; called by muse, mutect2, varscan2
- CHMP7 | c.558C>T p.L186= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs759170647, COSV57532165; called by muse, mutect2, varscan2
- CLCN1 | c.2565G>T p.G855= | Silent (SNP) | VAF 49/263 reads (19%) | catalogued as COSV58368943; called by muse, mutect2, varscan2
- CNTN2 | c.1617C>T p.D539= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV100084879; called by muse, mutect2
- COX8C | c.42C>T p.Y14= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99827201; called by muse, mutect2, varscan2
- CYP2A13 | c.846C>T p.P282= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs1261176842, COSV100386746, COSV57836975; called by muse, varscan2
- DCAF4L2 | c.471G>A p.V157= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs367787384, COSV60480425; called by muse, mutect2, varscan2
- DHX58 | c.1597C>A p.R533= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs550758764, COSV99288174; called by muse, mutect2, varscan2
- DOK5 | c.60C>T p.R20= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs1240376718, COSV52821369; called by muse, mutect2, varscan2
- DPP10 | c.309C>T p.V103= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100062576; called by muse, mutect2, varscan2
- DTX1 | c.1707G>T p.T569= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99921622; called by muse, mutect2, varscan2
- EGFL6 | c.120C>A p.V40= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100789872; called by muse, mutect2, varscan2
- ENPP6 | c.492C>T p.I164= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as COSV99698677; called by muse, mutect2, varscan2
- ERCC6L2 | c.1206A>G p.T402= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs990785109, COSV99998507; called by muse, mutect2, varscan2
- FAM71B | c.1011C>G p.S337= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV100262027, COSV57227585; called by muse, mutect2, varscan2
- FAT3 | c.706C>A p.R236= | Silent (SNP) | VAF 64/202 reads (32%) | catalogued as COSV53175999; called by muse, mutect2, varscan2
- FAT3 | c.8775G>C p.A2925= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV53094107, COSV53148581, COSV99964753; called by muse, mutect2, varscan2
- FREM2 | c.3846A>G p.T1282= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as COSV99748320; called by muse, mutect2, varscan2
- FZD10 | c.465G>T p.S155= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV57472461; called by muse, mutect2, varscan2
- GDF5 | c.765C>T p.P255= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100976793; called by muse, mutect2
- GFOD2 | c.549G>T p.V183= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99263504; called by muse, varscan2
- GGCX | c.777G>A p.G259= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as COSV99289849; called by muse, mutect2, varscan2
- GRAMD1B | c.1455G>T p.T485= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV100454594; called by muse, mutect2, varscan2
- GRID2 | c.402C>G p.T134= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99939564; called by muse, mutect2, varscan2
- GRIN2A | c.1581C>A p.P527= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs988901340, COSV100409367; called by muse, mutect2, varscan2
- HIPK4 | c.246C>T p.A82= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as rs755903863, COSV99396589; called by muse, mutect2, varscan2
- HIVEP2 | c.1212A>G p.S404= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as rs1266300288, COSV99172995; called by muse, mutect2, varscan2
- HORMAD1 | c.123C>T p.I41= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV100464027, COSV59270843; called by muse, mutect2
- IBTK | c.780A>G p.Q260= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs368349155; called by muse, mutect2, varscan2
- IGSF3 | c.1278G>A p.E426= (on ENST00000369486 / NM_001007237.3; = p.E446= on NM_001542.4) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100604508, COSV59587963; called by mutect2, varscan2
- INTS14 | c.729C>T p.I243= (on ENST00000313182 / NM_001366360.2; = p.I164= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs1302450441, COSV57527580; called by muse, mutect2, varscan2
- KCNH7 | c.1215T>G p.P405= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100035256; called by muse, mutect2, varscan2
- KMT2C | c.11613C>T p.D3871= | Silent (SNP) | VAF 45/347 reads (13%) | catalogued as rs369567780; called by muse, mutect2, varscan2
- KRTAP19-8 | c.191G>A p.*64= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV66998469; called by muse, mutect2, varscan2
- LARP1 | c.1605C>T p.V535= (on ENST00000518297 / NM_033551.3; = p.V458= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100303688; called by muse, mutect2, varscan2
- LRRTM3 | c.1404C>A p.S468= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100791596, COSV63669887; called by muse, mutect2, varscan2
- LRTOMT | c.192G>C p.L64= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99194394; called by muse, mutect2, varscan2
- LYPD6 | c.270C>T p.I90= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as rs367753547; called by muse, mutect2, varscan2
- MAT2B | c.660C>T p.F220= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99796607; called by muse, mutect2, varscan2
- MED12 | c.1206C>T p.S402= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV100377353; called by muse, mutect2, varscan2
- MGAT4C | c.1203G>A p.R401= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100152851; called by muse, mutect2, varscan2
- MIOS | c.1083C>T p.S361= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV100402678; called by muse, mutect2, varscan2
- MUC16 | c.23535C>A p.G7845= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV101199400; called by muse, mutect2, varscan2
- MYH4 | c.1923C>A p.G641= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV99700992; called by muse, mutect2, varscan2
- MYLK3 | c.1059G>A p.R353= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV101189078, COSV101189104; called by muse, mutect2, varscan2
- MYOC | c.1083T>C p.P361= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as rs1362986798, COSV99231430; called by muse, mutect2, varscan2
- NCAPD3 | c.3978A>T p.A1326= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV101592165; called by muse, mutect2, varscan2
- NETO2 | c.399A>G p.T133= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV100292405; called by muse, mutect2, varscan2
- NME8 | c.1101T>C p.N367= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV99553136; called by muse, mutect2, varscan2
- NR2C1 | c.1128C>T p.F376= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100280405; called by muse, mutect2, varscan2
- NRP2 | c.477C>T p.T159= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV99784074; called by muse, mutect2, varscan2
- NRXN1 | c.561G>A p.V187= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV101277479; called by muse, mutect2, varscan2
- NWD1 | c.1851C>T p.T617= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100342374; called by muse, mutect2, varscan2
- OR14A16 | c.720T>A p.L240= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100713751; called by muse, mutect2, varscan2
- OR2T3 | c.249G>T p.V83= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100613185; called by muse, mutect2, varscan2
- OR2T6 | c.345G>T p.L115= | Silent (SNP) | VAF 68/150 reads (45%) | catalogued as rs1187083168, COSV100861534; called by mutect2, varscan2
- OSBPL11 | c.1011G>A p.A337= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs774027543, COSV99954103, COSV99954108; called by muse, mutect2, varscan2
- PCDH9 | c.597G>A p.E199= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs760643967, COSV100119770; called by muse, mutect2, varscan2
- PCDHA3 | c.2131T>C p.L711= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV100793326; called by muse, mutect2, varscan2
- PCDHA6 | c.1863G>A p.P621= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs782199993, COSV65343457; called by muse, mutect2, varscan2
- PCDHGB2 | c.2109C>T p.F703= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1380837904, COSV99535761; called by muse, mutect2, varscan2
- PDHA2 | c.1089C>A p.G363= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs917016568, COSV99756770; called by muse, mutect2, varscan2
- PEAK3 | c.579G>T p.A193= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100574314, COSV100574366; called by muse, mutect2, varscan2
- PGBD2 | c.525G>T p.T175= | Silent (SNP) | VAF 37/231 reads (16%) | catalogued as COSV100251989; called by muse, mutect2, varscan2
- PLEKHH1 | c.3672C>T p.F1224= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100232997; called by muse, mutect2, varscan2
- POF1B | c.9G>T p.S3= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99426492; called by muse, varscan2
- POMGNT1 | c.555C>A p.L185= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100915517; called by muse, mutect2, varscan2
- POTEF | c.2508C>T p.I836= | Silent (SNP) | VAF 17/332 reads (5%) | catalogued as COSV62541283; called by muse, mutect2
- PSG3 | c.99T>A p.T33= | Silent (SNP) | VAF 39/228 reads (17%) | catalogued as COSV100548875; called by muse, mutect2, varscan2
- PSG7 | c.324G>A p.L108= | Silent (SNP) | VAF 73/540 reads (14%) | catalogued as COSV101343225; called by muse, mutect2, varscan2
- PYCARD | c.587G>A p.*196= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs770638973, COSV99910907; called by muse, mutect2, varscan2
- RGS6 | c.483G>A p.R161= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100665840; called by muse, mutect2, varscan2
- RIPOR1 | c.1960C>T p.L654= (on ENST00000379312 / NM_001193522.2; = p.L650= on NM_024519.4) | Silent (SNP) | VAF 61/211 reads (29%) | catalogued as COSV99242938; called by muse, mutect2, varscan2
- ROBO3 | c.1020C>A p.S340= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101185011; called by muse, mutect2
- RP2 | c.216C>T p.I72= | Silent (SNP) | VAF 55/99 reads (56%) | catalogued as COSV99509128; called by muse, mutect2, varscan2
- RPS6KB2 | c.510G>T p.T170= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV100412206, COSV57048623; called by muse, mutect2, varscan2
- RUNDC3A | c.1008C>G p.L336= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99835192; called by muse, mutect2, varscan2
- SEMA4D | c.1392C>G p.T464= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs1359870823, COSV100358199; called by muse, mutect2, varscan2
- SHOC1 | c.4299T>C p.G1433= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV100597501; called by muse, mutect2, varscan2
- SLAMF9 | c.573G>T p.P191= | Silent (SNP) | VAF 70/171 reads (41%) | catalogued as COSV100928126, COSV63636331, COSV63637241; called by muse, mutect2, varscan2
- SLC9B1 | c.252C>T p.I84= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99599473; called by muse, mutect2, varscan2
- SORT1 | c.756C>T p.I252= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99860651; called by muse, mutect2, varscan2
- SPRR1B | c.69G>A p.Q23= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as rs960528324, COSV100198345; called by muse, mutect2
- STAC | c.615C>T p.F205= | Silent (SNP) | VAF 66/200 reads (33%) | catalogued as rs752252190, COSV56210826, COSV99830682; called by muse, mutect2, varscan2
- STAC3 | c.699G>A p.E233= | Silent (SNP) | VAF 29/279 reads (10%) | catalogued as rs772998691, COSV100234565; called by muse, mutect2, varscan2
- SYN3 | c.519G>T p.L173= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100248024; called by muse, mutect2, varscan2
- SYNE1 | c.17154G>A p.E5718= (on ENST00000367255 / NM_182961.4; = p.E5647= on NM_033071.3) | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs756664669, COSV99560446; called by muse, mutect2, varscan2
- SYNE1 | c.10269G>C p.R3423= (on ENST00000367255 / NM_182961.4; = p.R3430= on NM_033071.3) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs1019631406, COSV99560456; called by muse, mutect2, varscan2
- TBX20 | c.69C>A p.L23= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV101282371; called by muse, varscan2
- TG | c.7368G>A p.Q2456= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV99600265; called by muse, mutect2, varscan2
- TGFBRAP1 | c.306C>T p.V102= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs774096145, COSV99304983; called by muse, mutect2, varscan2
- TLCD1 | c.378C>T p.F126= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99261754; called by muse, varscan2
- TLL2 | c.2115G>A p.S705= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as rs762506874, COSV100780234; called by muse, mutect2, varscan2
- TNIP3 | c.330C>A p.R110= | Silent (SNP) | VAF 88/387 reads (23%) | catalogued as COSV50245946; called by muse, varscan2
- TNN | c.3247C>T p.L1083= | Silent (SNP) | VAF 18/132 reads (14%) | called by mutect2, varscan2
- TOGARAM1 | c.2694G>A p.V898= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV100817977; called by muse, mutect2, varscan2
- TPR | c.2346A>G p.E782= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs765835317, COSV66599166, COSV66600323; called by muse, mutect2, varscan2
- TPTE2 | c.765G>A p.K255= (on ENST00000400230 / NM_199254.2; = p.K178= on NM_130785.3) | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99690120; called by muse, mutect2, varscan2
- TTN | c.78399C>T p.T26133= (on ENST00000591111; = p.T18709= on NM_003319.4) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs558052778, COSV100605647; called by muse, varscan2
- VAV2 | c.1971C>T p.P657= (on ENST00000371850 / NM_001134398.2; = p.P647= on NM_003371.4) | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs958128439, COSV100895688; called by muse, mutect2, varscan2
- WNT10B | c.975C>A p.G325= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1255663909, COSV99975893; called by muse, varscan2
- XIRP2 | c.402T>A p.G134= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as COSV99741580; called by muse, mutect2, varscan2
- ZAP70 | c.456C>G p.L152= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99385411; called by muse, varscan2
- ZBED9 | c.2199C>T p.F733= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs267600927, COSV71729189; called by mutect2, varscan2
- ZFPM2 | c.2142C>T p.H714= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1342370380, COSV101023163; called by muse, mutect2, varscan2
- ZMYM3 | c.1497C>G p.V499= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs914460630, COSV100077731; called by muse, mutect2, varscan2
- ZNF208 | c.1908C>A p.P636= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as rs1427668778, COSV101236986; called by muse, varscan2
- ZNF266 | c.1389A>C p.P463= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100749369; called by muse, mutect2
- ZNF536 | c.1338G>C p.L446= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100835055; called by muse, mutect2, varscan2
- ZNF549 | c.981T>C p.N327= (on ENST00000376233 / NM_001199295.2; = p.N314= on NM_153263.2) | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99558481; called by muse, mutect2, varscan2
- AC074085.2 | n.48C>T | RNA (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-177457T>A | Intron (SNP) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- AL590867.2 | n.306T>A | RNA (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- ARRDC1 | chr9:137615774 C>T | 3'Flank (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- CDKL1 | c.742-1516A>G | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs1457909172, COSV99367349; called by muse, varscan2
- IQSEC3 | c.3114+137G>A | Intron (SNP) | VAF 10/208 reads (5%) | catalogued as rs782741466, COSV100407056, COSV58290517; called by muse, mutect2
- MICAL3 | c.2605+159G>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99261159; called by muse, mutect2, varscan2
- MIR518F | n.83T>C | RNA (SNP) | VAF 14/66 reads (21%) | catalogued as rs1254264046; called by muse, mutect2
- SH2D6 | n.400T>A | RNA (SNP) | VAF 28/122 reads (23%) | catalogued as COSV100442509; called by muse, mutect2, varscan2
- SH2D6 | n.401C>A | RNA (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100442511; called by muse, mutect2, varscan2
- TTN | c.10360+5071G>C | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100605655; called by muse, mutect2
